Somatic mutation profile of tumor specimen TCGA-HU-A4G6-01A (aliquot TCGA-HU-A4G6-01A-11D-A24D-08) from TCGA case TCGA-HU-A4G6, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 74.5 years (27,208 days).
Specimen TCGA-HU-A4G6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bfbee50-9578-413b-8127-0f34079591e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HU-A4G6-10A (Blood Derived Normal), aliquot TCGA-HU-A4G6-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14b862c8-ded7-46e1-8a1c-1dd841709e56

The open-access MAF lists 85 somatic variants for this specimen: 63 protein-altering or splice-affecting, 21 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 21, Frame Shift Del 4, Nonstop Mutation 1, RNA 1, In Frame Del 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 15/19 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913399, COSV62687911, COSV62687931, COSV62721471; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.2563T>A p.F855I | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV64984452; called by muse, mutect2, varscan2
- ADGRL4 | c.347A>T p.H116L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.035); catalogued as COSV100875967, COSV66058997; called by muse, mutect2, varscan2
- ARFGEF2 | c.2428C>A p.L810M | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64210259; called by muse, mutect2, varscan2
- AVEN | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60732098; called by muse, mutect2, varscan2
- CARMIL3 | c.4000C>T p.R1334W | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs757377104, COSV53742395; called by muse, mutect2, varscan2
- CBY2 | c.329C>A p.A110D | Missense Mutation (SNP) | VAF 28/139 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60117142; called by muse, mutect2, varscan2
- CCDC15 | c.200A>T p.E67V | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV61080137; called by muse, mutect2
- CELSR2 | c.6670G>A p.A2224T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.038); catalogued as COSV54766495; called by muse, mutect2, varscan2
- CFAP206 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as COSV51532449; called by muse, mutect2, varscan2
- CFAP46 | c.7970G>A p.R2657H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.029); catalogued as rs766366866; called by mutect2, varscan2
- DDIAS | c.2294G>C p.S765T | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.294); catalogued as COSV61271311; called by muse, mutect2, varscan2
- DDX1 | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.68); PolyPhen benign (0.036); catalogued as rs1233607382, COSV51837837; called by muse, mutect2, varscan2
- DDX43 | c.415T>G p.Y139D | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.547); catalogued as COSV64836345; called by muse, mutect2, varscan2
- DLG5 | c.3518C>T p.P1173L | Missense Mutation (SNP) | VAF 60/127 reads (47%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs759311731, COSV64946615; called by muse, mutect2, varscan2
- DUOX1 | c.2855G>A p.R952Q | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as rs975294988, COSV58477116; called by muse, mutect2, varscan2
- FAM153A | c.646C>A p.L216M | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV62360953; called by muse, mutect2, varscan2
- FAT4 | c.2262A>C p.E754D | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as COSV67880990; called by muse, mutect2, varscan2
- GIPC1 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.179); catalogued as rs151133470; called by muse, mutect2, varscan2
- GTSE1 | c.1798C>T p.P600S | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.858); catalogued as COSV71888913; called by muse, mutect2, varscan2
- HEATR1 | c.4202A>C p.Q1401P | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV63979737; called by muse, mutect2, varscan2
- HOXD9 | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.817); catalogued as COSV50890510; called by mutect2, varscan2
- KCNA10 | c.1534T>G p.*512Gext*? | Nonstop Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV63904174; called by muse, mutect2, varscan2
- KCNQ3 | c.637G>T p.V213F | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as COSV66463423; called by muse, mutect2, varscan2
- KLHL7 | c.745G>C p.A249P (on ENST00000339077 / NM_001031710.3; = p.A201P on NM_018846.5) | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV59159610; called by muse, mutect2, varscan2
- MEF2A | c.569C>T p.S190F (on ENST00000557942 / NM_001319206.2; = p.S192F on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV57529688; called by muse, mutect2, varscan2
- MUC16 | c.5060G>T p.S1687I | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.686); catalogued as COSV67443154; called by muse, mutect2, varscan2
- MUC3A | c.8921G>A p.G2974E | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs759534118, COSV60210190, COSV60226222; called by muse, mutect2, varscan2
- MYO3A | c.1660A>T p.R554W | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56319018; called by muse, mutect2, varscan2
- MYOZ3 | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs765485012, COSV51738818; called by muse, mutect2, varscan2
- NBEA | c.7726C>A p.P2576T | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV59758966; called by muse, mutect2, varscan2
- NEFH | c.1861C>A p.P621T | Missense Mutation (SNP) | VAF 44/68 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV60214893; called by muse, mutect2, varscan2
- NFASC | c.361C>T p.R121C (on ENST00000339876 / NM_001378329.1; = p.R115C on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1001294514, COSV58358205; called by muse, mutect2, varscan2
- NLRC3 | c.355G>T p.A119S | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV57086842; called by muse, mutect2, varscan2
- NOTCH1 | c.7112C>G p.T2371S | Missense Mutation (SNP) | VAF 53/137 reads (39%) | SIFT tolerated (0.75); PolyPhen benign (0.026); catalogued as rs755417102, COSV53026874; called by muse, mutect2, varscan2
- NPHP1 | c.2183G>A p.R728K (on ENST00000393272 / NM_207181.4; = p.R729K on NM_000272.5) | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.194); catalogued as rs753549193, COSV57206308; called by muse, mutect2, varscan2
- OR52A5 | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100263259, COSV56614108; called by muse, mutect2, varscan2
- PLXNA3 | c.4954G>A p.E1652K | Missense Mutation (SNP) | VAF 32/35 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63753106; called by muse, mutect2, varscan2
- PRAMEF14 | c.569C>T p.T190M | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.342); catalogued as rs1268745944; called by mutect2, varscan2
- PTPRT | c.3522A>C p.Q1174H | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.928); catalogued as COSV61958926; called by muse, mutect2, varscan2
- RSPH10B2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1189036029, COSV99786030; called by mutect2, varscan2
- RYR3 | c.10099G>A p.V3367M (on ENST00000389232; = p.V3368M on NM_001036.6) | Missense Mutation (SNP) | VAF 29/45 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761453884, COSV66777080; called by muse, mutect2, varscan2
- SCN9A | c.5656C>T p.R1886W (on ENST00000303354; = p.R1875W on NM_002977.3) | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs560168893, COSV57599473; called by muse, mutect2, varscan2
- SEMA5B | c.2992G>A p.A998T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs767386549, COSV52090097; called by muse, mutect2, varscan2
- SEMA6D | c.2587T>C p.S863P (on ENST00000316364 / NM_153618.2; = p.S801P on NM_020858.2) | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV60372356; called by muse, mutect2, varscan2
- SEZ6L | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs752901613, COSV50657778; called by muse, mutect2, varscan2
- SMARCA1 | c.2038A>T p.K680* | Nonsense Mutation (SNP) | VAF 49/56 reads (88%) | catalogued as COSV64410719; called by muse, mutect2, varscan2
- SORCS3 | c.3076G>T p.G1026C | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV63793204; called by muse, mutect2, varscan2
- SOX8 | c.1058G>A p.R353Q | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs375735232; called by muse, mutect2, varscan2
- ST7 | c.1055A>C p.Q352P (on ENST00000265437 / NM_021908.3; = p.Q329P on NM_018412.4) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55379634; called by muse, mutect2, varscan2
- TLN1 | c.2747G>A p.R916H | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as rs760405428, COSV59203837; called by muse, mutect2, varscan2
- TMCO3 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs145599687; called by muse, mutect2, varscan2
- TPRN | c.1529G>T p.G510V | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated (0.22); PolyPhen benign (0.163); catalogued as COSV58806235; called by muse, mutect2, varscan2
- WIPF1 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55811195; called by muse, mutect2, varscan2
- ZER1 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52563913; called by muse, mutect2, varscan2
- ZNF567 | c.1598A>C p.Y533S (on ENST00000536254 / NM_001322913.1; = p.Y502S on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV62444051; called by muse, mutect2, varscan2
- ARID1A | c.4136del p.P1379Lfs*102 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- DXO | c.616_639del p.P206_N213del | In Frame Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel
- LIPF | c.1087del p.Y363Tfs*30 | Frame Shift Del (DEL) | VAF 38/99 reads (38%) | called by mutect2, pindel, varscan2
- PRKCA | c.682_686+13del p.X228_splice | Splice Site (DEL) | VAF 28/73 reads (38%) | called by mutect2, pindel
- RNF128 | c.21_22del p.S8Ffs*13 | Frame Shift Del (DEL) | VAF 24/33 reads (73%) | called by mutect2, pindel, varscan2
- TENT5C | c.286del p.H96Mfs*22 | Frame Shift Del (DEL) | VAF 37/92 reads (40%) | called by mutect2, pindel, varscan2
- TMEM185A | c.746C>T p.P249L | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACTRT1 | c.777C>T p.P259= | Silent (SNP) | VAF 135/148 reads (91%) | catalogued as rs374313675, COSV64418909; called by muse, mutect2, varscan2
- ADRB2 | c.1071C>T p.N357= | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs761680537, COSV60005130; called by muse, mutect2, varscan2
- AK3 | c.147C>T p.G49= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1409767324; called by mutect2, varscan2
- C8orf74 | c.462C>T p.A154= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV100262170, COSV58753498; called by muse, mutect2, varscan2
- CACNA1C | c.1863C>T p.C621= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs747010529, COSV100216001, COSV59695689; called by muse, mutect2, varscan2
- CCNA1 | c.1038G>A p.Q346= | Silent (SNP) | VAF 92/169 reads (54%) | catalogued as COSV55219786; called by muse, mutect2, varscan2
- CNGB1 | c.138C>T p.A46= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs753557311, COSV51897339; called by muse, mutect2, varscan2
- F11 | c.1791A>G p.E597= | Silent (SNP) | VAF 17/58 reads (29%) | catalogued as COSV53001215; called by muse, mutect2, varscan2
- FGF6 | c.141G>A p.T47= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs921604607, COSV57403266, COSV57404458; called by muse, mutect2, varscan2
- GLB1 | c.1563C>T p.C521= | Silent (SNP) | VAF 32/41 reads (78%) | catalogued as COSV56561226; called by muse, mutect2, varscan2
- IYD | c.366G>A p.T122= | Silent (SNP) | VAF 28/86 reads (33%) | catalogued as rs774946469, COSV57599225; called by muse, mutect2, varscan2
- MTUS1 | c.1257C>G p.V419= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV50550601; called by muse, mutect2, varscan2
- NLRP3 | c.1740C>T p.G580= | Silent (SNP) | VAF 3/45 reads (7%) | catalogued as rs1489433249, COSV60219451; called by muse, mutect2
- SCP2D1 | c.393C>T p.A131= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs369264069; called by muse, mutect2, varscan2
- SERPINB2 | c.459C>T p.P153= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs778529592, COSV55090957; called by muse, mutect2, varscan2
- SPTA1 | c.3688A>C p.R1230= | Silent (SNP) | VAF 34/61 reads (56%) | catalogued as COSV63748596; called by muse, mutect2, varscan2
- TLK1 | c.1971A>G p.V657= | Silent (SNP) | VAF 112/235 reads (48%) | catalogued as rs780241476, COSV62628786; called by muse, mutect2, varscan2
- TTC30B | c.330C>T p.A110= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV68809196; called by muse, mutect2, varscan2
- TTN | c.101685C>G p.V33895= (on ENST00000591111; = p.V26471= on NM_003319.4) | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV59875339; called by muse, varscan2
- USP9X | c.750A>G p.Q250= | Silent (SNP) | VAF 37/40 reads (93%) | catalogued as rs771426271, COSV61065610; called by muse, mutect2, varscan2
- WASHC2C | c.3948G>A p.Q1316= (on ENST00000336378; = p.Q1295= on NM_015262.3 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 23/121 reads (19%) | catalogued as rs1435824301; called by muse, mutect2, varscan2
- MIR181B1 | n.107G>A | RNA (SNP) | VAF 24/60 reads (40%) | catalogued as rs536070800; called by muse, mutect2, varscan2
